Somatic mutation profile of tumor specimen TCGA-D3-A51K-06A (aliquot TCGA-D3-A51K-06A-11D-A25O-08) from TCGA case TCGA-D3-A51K, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 52.0 years (18,991 days).
Specimen TCGA-D3-A51K-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b8e90a1-bfd2-4222-bf69-883682b07094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51K-10A (Blood Derived Normal), aliquot TCGA-D3-A51K-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/939815a1-6e6f-4757-94a7-850d948d1994

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 511/536 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs121913513, CM133722, COSV55386593, COSV55412340; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ANK1 | c.3893C>A p.S1298Y | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55895515; called by muse, mutect2, varscan2
- CAVIN1 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.116); catalogued as COSV100824493, COSV63812761; called by muse, mutect2, varscan2
- CCDC158 | c.544C>A p.H182N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV66357172; called by muse, mutect2, varscan2
- DELE1 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52006570; called by muse, mutect2, varscan2
- FBXO33 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53235960; called by muse, mutect2, varscan2
- KDR | c.2180T>G p.V727G | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55775782; called by muse, mutect2, varscan2
- LUC7L3 | c.578A>C p.E193A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53589468; called by muse, mutect2, varscan2
- MACF1 | c.5218G>T p.G1740W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57143415; called by muse, mutect2, varscan2
- MGAT4C | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV59837639; called by muse, mutect2, varscan2
- NFATC4 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.349); catalogued as rs144789611; called by muse, mutect2, varscan2
- OR14A16 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs1002086000, COSV62927451; called by muse, mutect2, varscan2
- OR4S1 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs1216925561, COSV60679991; called by muse, mutect2, varscan2
- PARP4 | c.4793T>G p.L1598R | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV67964146; called by muse, mutect2, varscan2
- PCNX2 | c.5407C>T p.R1803C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222122993, COSV50886159; called by muse, mutect2
- RDH5 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV57677353; called by muse, varscan2
- SLC7A14 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.952); catalogued as COSV51589921; called by muse, mutect2, varscan2
- SPATC1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV66300018; called by muse, mutect2, varscan2
- STING1 | c.244T>C p.W82R | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV58173477; called by muse, mutect2, varscan2
- SYNE1 | c.9385G>T p.E3129* (on ENST00000367255 / NM_182961.4; = p.E3136* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 56/68 reads (82%) | catalogued as COSV55097946, COSV99573026; called by muse, mutect2, varscan2
- WDR13 | c.493C>G p.H165D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54333534; called by muse, varscan2
- KCNG2 | c.795G>A p.S265= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs934179831, COSV60270333; called by muse, mutect2
- NOXRED1 | c.657A>G p.Q219= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV53629160; called by muse, mutect2, varscan2
- NYAP2 | c.423C>T p.P141= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV56016318, COSV99797963; called by muse, mutect2, varscan2
- PTDSS2 | c.663C>T p.S221= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs771722702, COSV57278063; called by muse, mutect2, varscan2
- TRARG1 | c.423C>T p.G141= | Silent (SNP) | VAF 74/159 reads (47%) | catalogued as rs372463560; called by muse, mutect2, varscan2
